Surgical pathology report (de-identified scan), TCGA case TCGA-FP-A9TM, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-FP-A9TM-01A (Primary Tumor).

[page 1 of 6]
Referring Physician:

DOB: Age: Gender: M

Ref#: Hosp#: Patient Location:

Date of Service: Date Received:

Case #:

Date Reported:

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

ICD O-3

Adenocarcinoma NOS 8140/3
Site: Gastroesophageal junction C16.0
MO 01/01/14

A. GALLBLADDER, CHOLECYSTECTOMY:

- FUNDAL ADENOMYOMA.
- ONE BENIGN LYMPH NODE (0/1).
- NEGATIVE FOR DYSPLASIA AND MALIGNANCY.

B. APPENDIX, APPENDECTOMY:

- NO DIAGNOSTIC ALTERATION.
- NEGATIVE FOR DYSPLASIA AND MALIGNANCY.

C. - D. STOMACH AND FINAL ESOPHAGEAL MARGIN, TOTAL GASTRECTOMY WITH PROXIMAL MARGIN EXCISION:

- INVASIVE ADENOCARCINOMA, MODERATELY DIFFERENTIATED.
- Size 2.9 cm.
- Tumor invades submucosa.
- Positive for lymphovascular invasion.
- MARGINS NEGATIVE FOR MALIGNANCY.
- TWO OF TWENTY-FIVE LYMPH NODES POSITIVE FOR METASTASIS (2/25).

PATHOLOGIC TUMOR STAGING SUMMARY:

Histologic type and grade: Esophagogastric junction (Gastric cardia)
Adenocarcinoma, Grade 2.

Primary tumor: pT1b.

Regional lymph nodes: pN1.

Distant metastasis: Not applicable.

Pathologic stage: IIB.

Margin status: R0, negative.

Lymphovascular invasion: Positive.

Perineural invasion: Negative.

Case #:

Printed:

Page 1

This report continues... (FINAL)

[page 2 of 6]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol, June, 2012.

Case #
Printed:

Page 2
This report continues... (FINAL)

[page 3 of 6]
Patient: _____

Case #

Specimen:	Total stomach.
Procedure:	Total gastrectomy.
Tumor site:	Gastric cardia.
Relationship of tumor to esophageal gastric junction:	Tumor mid-point lies in the proximal stomach (cardia) and tumor involves the esophagogastric junction.
Tumor size:	2.9 x 1.8 cm.
Histologic type:	Adenocarcinoma.
Histologic grade:	Grade 2, moderate.
Microscopic tumor extension:	Tumor invades submucosa.

Margins:	
Proximal margin:	Negative.
Distal margin:	Negative.
Circumferential margin:	Negative.

Treatment effect:	Not applicable.
Lymphovascular invasion:	Positive.
Perineural invasion:	Not identified.

Pathologic tumor staging summary:	
Primary tumor:	pT1b.
Regional lymph nodes:	pN1.
Distant metastasis:	N/A.

Additional pathologic findings:	Severe antral chemical gastritis with focal activity and foveolar hyperplasia. Fundic gland polyps. Hyperplastic polyps.
---------------------------------	--

Case #:
Printed:

[page 4 of 6]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

Signed by

Source of Specimen:

- A. Gallbladder
- B. Appendix
- C. Total gastrectomy
- D. Esophagus, final esophageal margin (frozen section)

Clinical History/Operative Dx:

Stomach cancer.

Intraoperative Diagnosis:

- D. Final esophageal margin (FSD1):
- Final margin negative.

Reported by

The intraoperative interpretation(s) was/were performed and rendered at

Gross Description:

A. Received in a formalin container labeled as A per requisition is an intact gallbladder measuring 9.9 x 3.3 x 2.8 cm. The serosa is glistening, tense, partially fatty and tan-green. The wall is 0.1 to 0.3 cm, including serosal fat, and the lumen contains a copious amount of viscous, dark green bile without calculi. The bile is strained along with the contents of the container, and no calculi/particulate matter is appreciated. The wall of the dome is thickened up to 0.8 cm over an area of 1.3 x 0.8 cm. The cut surface demonstrates minute to 0.2 cm cystic/fluid-filled spaces. The mucosa is thin, velvety, semi-congested, red and tan-green without additional, grossly unusual areas of change. Representative sections are submitted for microscopic evaluation including representation of the cystic duct margin (orange), mid fundus and thickened area of fundus (entirely submitted) in A1. [REDACTED]

B. Received in a formalin container labeled as B per requisition is a vermiform appendix measuring 6.6 x 0.7 cm. The serosa is hyperemic, pink and tan. Sectioning demonstrates a 0.2 to 0.4 cm lumen containing watery, dark green fecal matter. There is no well-organized fecolith, and the wall appears intact. Representative sections are submitted for microscopic evaluation, including entire submission of the bisected apex, representation of the proximal surgical margin (orange) and mid length in B1. [REDACTED]

C. Received within a fresh state in a container labeled "total gastrectomy" is an apparent total gastrectomy specimen measuring 30.1 cm along the greater curvature, and 21.0 cm along the lesser curvature. The esophageal margin is 2.5 cm in diameter, the radius of which is now marked black. The apparent distal margin of resection is up to 3.5 cm in diameter. The gastric serosa is hyperemic pink and

Case #:

Printed:

Page 4

This report continues... (FINAL)

[page 5 of 6]
Patient:

Case #.

FINAL SURGICAL PATHOLOGY REPORT

tan, with increased purple-red hemorrhagic congestion towards the proximal margin of resection. An abundant amount of perigastric fat is present along the lesser curvature, extending out to 6.7 cm, while the greater curvature is predominantly absent of fat. The length of the specimen is opened along the greater curvature, revealing a irregular, dusky red tumor mass, abutting the proximal margin of resection, at the edge of the lesser curvature, measuring upwards of 2.9 x 1.8 cm and raised to 0.5 cm. Sectioning through the lesion demonstrates possible invasion into the gastric wall, however, appears grossly confined, within 0.2 cm of the radial surgical margin (C1).

Scattered throughout the stomach are several grossly confined, delicate light pink and tan polyps ranging from 0.3 - 0.6 cm (x10). Within 2.5 cm of the apparent distal margin of resection, approximating the pylorus, the mucosa demonstrates a raised dusky red appearance over an area of 4.7 x 1.6 cm. Sectioning through this apparent lesion demonstrates gross confinement to the mucosa. No additional lesions appreciated.

Examination of the perigastric fat of the lesser curvature reveals twenty-three lymph nodes ranging from 0.2 - 0.7 cm, soft to rubbery and firm light pink and tan. Lymph node tissue is entirely submitted for microscopic evaluation.

Cassette summary:

- C1) proximal margin of resection (orange), lesion relationship at invasive tumor relationship,
- C2-C7) mass near proximal gastric margin, blocked out, sectioned and entirely submitted,
- C8) distal margin of resection trimmed and submitted,
- C9) two polyps,
- C10) ten polyps,
- C11) two polyps,
- C12) six polyps,
- C13-C18) mass near distal margin of resection, blocked out and submitted,
- C19) mid and proximal stomach possible additional polyps,
- C20) distal end of stomach, including possible small bowel,
- C21) six lymph nodes,
- C22) six lymph nodes,
- C23) six lymph nodes,
- C24) five lymph nodes,
- C25) five lymph nodes.

D. Initially received in the fresh state for frozen section evaluation is a 2.5 x 2.2 x 1.5 cm portion of esophageal tissue. The apparent mucosa is glistening, light tan to deep red without gross tumor involvement. A suture marks the final margin (oriented by) and the specimen is held together by a purse string suture. The final margin is now trimmed and submitted for frozen section evaluation with the residual frozen tissue submitted in D1 for permanent sections. The remainder of the specimen is submitted from final margin end towards opposite end in D2 and D3.

Microscopic Description:

Case #:

Printed:

Page 5

This report continues. (FINAL)

[page 6 of 6]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

A. Sections of the gallbladder show benign glandular extension into the wall of the fundus with prominent dilatation consistent with an adenomyoma. There is a single benign lymph node (0/1). No dysplasia or malignancy is identified.

B. Sections of the appendix show an unremarkable appendix. There is a rare gland with a few neutrophils in the lumen but no significant activity is present. No dysplasia or malignancy is identified.

C. Sections of the total gastrectomy show an adenocarcinoma arising just distal to the esophagogastric junction. The tumor is primarily gland forming (>50%) with areas of abundant extracellular mucin. In some areas, the tumor forms microglands, small nests and occasional single cells. There are a few scattered signet ring cell forms but these are not the predominant cell type. The tumor invades the submucosa but no tumor involvement of the muscularis propria is identified. A focus of lymphatic invasion is present. No perineural invasion is identified. The distal and circumferential margin is uninvolved.

A total of twenty-five lymph nodes are identified. There are two lymph nodes with metastatic adenocarcinoma in the subcapsular sinus (2/25). No extracapsular extension is present.

There are multiple fundic gland polyps and a few small hyperplastic polyps. The polyps are free of dysplasia. The gastric antrum has prominent chemical gastropathy with a few focal areas of activity and relatively diffuse foveolar hyperplasia.

D. The sections of the final proximal esophageal margin show benign esophageal wall without tumor involvement. No malignancy is identified.

Case #:

Printed:

Page 6

REPRINT: Orig. printing on

Source: NCI Genomic Data Commons file 32adc5f8-6e83-4d1e-ab61-3ec90fd2326b (TCGA-FP-A9TM.B71E9275-85C4-46AF-8234-1C850C7D2536.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).